Surgical pathology report (de-identified scan), TCGA case TCGA-GJ-A3OU, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GJ-A3OU-01A (Primary Tumor).

[page 1 of 2]
100-0-3

Operative Procedure:
Laparoscopic right hepatectomy

*Carcinoma, Hepatocellular, NOS (8170/3) and
clear cell type (8174/3) - code to highest - 8174/3
Site: liver C22.0*

Specimen Received:
Segment 8 hepatectomy

*fw
2/15/12*

Final Pathologic Diagnosis:
Liver, segment 8, laparoscopic right hepatectomy:
Hepatocellular carcinoma, with clear cell features,
moderately-differentiated, see synoptic report.

Liver cancer synoptic report

Specimen: Segment 8 of liver
Procedure: Laparoscopic right hepatectomy
Tumor histologic type: Hepatocellular carcinoma
Tumor size: 2.7 cm (greatest dimension)
Tumor focality: Unifocal
Number of tumors: One
Histologic type: Hepatocellular carcinoma with clear cell
features
Histologic grade: Moderately-differentiated
Tumor extension: Tumor confined to liver
Margins:
Parenchymal: Uninvolved
Distance of invasive carcinoma from closest
margin: 1.6 cm
Other margin: Not applicable
Lymph-vascular invasion:
Macroscopic venous (large vessel) invasion: Not identified
Microscopic (small vessel) invasion: Absent
Pathologic staging: (pTMN)
TNM descriptors: None known
Primary tumor (pT): pT1
Regional lymph nodes (pN): pNX, lymph nodes not examined
Distant metastasis (pM): Not applicable

Additional pathologic findings: Cirrhosis; Steatosis

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received is a single formalin-filled container labeled with the patient's name and "segment 8 hepatectomy." The specimen consists of a portion of liver measuring 10.5 x 7.8 x 2.5 cm. The specimen is previously inked and dissected. The liver capsule is brown-tan smooth and lobulated. Further

Diagnosis Discrepancy	wt 55% clear cell ✓	☒

[page 2 of 2]
sectioning reveals yellow-tan, firm, irregular ill defined mass measuring 2.7 x 2.3 x 1.8 cm. The mass abuts to the liver capsule and 1.6 cm from the nearest resection margin. The rest of the liver parenchyma is brown-tan and finely nodulated. Representative sections are submitted as follows:

- 1-2 The mass to the inked surgical margin
- 3-5 The mass to the liver capsule
- 6-7 The mass with adjacent liver parenchyma
- 8-9 Uninvolved liver parenchyma

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: (Age: Gender:

Source: NCI Genomic Data Commons file d5ecadf4-524f-4695-8e98-a35912ac90ac (TCGA-GJ-A3OU.4ABC92BD-6D5C-462D-8DDC-2A3CEE065C13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).